Somatic mutation profile of tumor specimen MP2PRT-PARYFJ-TMP1-A (aliquot MP2PRT-PARYFJ-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARYFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,274 days).
Specimen MP2PRT-PARYFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c96a9f12-30ad-4786-a1f2-e496ff331cd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARYFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARYFJ-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb8bf924-062c-4ee8-8a40-c9274d341323

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 62/614 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs867199147; called by muse, mutect2
- EVC | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 88/665 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs757990300, COSV53834741; called by muse, mutect2, varscan2
- RYR1 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 170/1012 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs148146893; called by muse, mutect2, varscan2
- ZNF185 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 90/707 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs895396553, COSV59274098; called by muse, mutect2, varscan2
- FBXO3 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MROH5 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 105/579 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS17 | c.1725T>A p.P575= | Silent (SNP) | VAF 16/476 reads (3%) | called by muse, mutect2
- KCNH1 | c.930C>T p.N310= | Silent (SNP) | VAF 69/407 reads (17%) | catalogued as rs776240703, COSV55089116; called by muse, mutect2, varscan2
- SHROOM1 | c.717G>A p.A239= | Silent (SNP) | VAF 127/1286 reads (10%) | catalogued as COSV60581506; called by muse, mutect2
- TBKBP1 | c.39G>A p.T13= | Silent (SNP) | VAF 93/794 reads (12%) | catalogued as rs762201898; called by muse, mutect2, varscan2
